Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4T6, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4T6-01A (Primary Tumor).

		10/24/12

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 C1 D1 D2 E1 E2 E3 E4 F1 G1 G2 G3 G4 G5
Left lower lobe lung (140.0 grams), left upper lobe lung lymph node, station 4L, 6, and 7 lymph nodes.

DIAGNOSIS:

Lung, left lower, lobectomy: Invasive grade 3 (of 4) adenocarcinoma forming a 2.5 x 2.5 x 2.5 cm subpleural mass that abuts but does not involve the puckered pleural surface. The bronchial resection margin is free of tumor.

Lymph nodes, left upper lung, excision:

-A single lymph node is positive for metastatic adenocarcinoma.

Lymph nodes, intrapulmonary/hilar, excision:

-Metastatic adenocarcinoma is identified in multiple (3 of 4) intrapulmonary peribronchial lymph nodes.

Lymph nodes, left mediastinal, excision:

-Metastatic adenocarcinoma is identified in multiple (3 of 25) subcarinal (station 7) lymph nodes.

-No tumor is identified in multiple (5) left lower paratracheal (station 4L) lymph nodes.

-No tumor is identified in a single (of 1) para-aortic (station 6) lymph node.

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: lung @ lower lobe C34.3

lu
10/24/12

Source: NCI Genomic Data Commons file f4f9d77d-9aa1-48fd-b130-494a0df6e750 (TCGA-MP-A4T6.2FAB9F3E-DD9B-45AF-9160-D23ECCA95A2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).